Somatic mutation profile of tumor specimen TCGA-FG-A87N-01A (aliquot TCGA-FG-A87N-01A-11D-A36O-08) from TCGA case TCGA-FG-A87N, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 37.3 years (13,606 days).
Specimen TCGA-FG-A87N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 391c588d-6e95-4663-b021-01e40f5d56da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A87N-10A (Blood Derived Normal), aliquot TCGA-FG-A87N-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0d3f3a9-3bc5-4d64-a260-57e182570649

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 15, Silent 8, Splice Site 3, Frame Shift Ins 2, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NF1 | c.5269-1G>C p.X1757_splice (on ENST00000358273 / NM_001042492.3; = p.X1736_splice on NM_000267.3) | Splice Site (SNP) | VAF 45/47 reads (96%) | catalogued as rs876660141, CS1411400, CS153442, COSV62192457; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAGAB | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99972011; called by muse, mutect2, varscan2
- ACSL4 | c.1825C>A p.Q609K (on ENST00000340800 / NM_022977.2; = p.Q568K on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100538857; called by muse, mutect2, varscan2
- ADAMTS3 | c.533A>T p.E178V | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99711722; called by muse, mutect2, varscan2
- BEND7 | c.504del p.V169Cfs*11 | Frame Shift Del (DEL) | VAF 49/132 reads (37%) | catalogued as rs1473522448; called by mutect2, pindel, varscan2
- CDR2 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs745563185, COSV51675522; called by muse, mutect2
- CENPF | c.5212A>T p.K1738* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100871842; called by muse, mutect2, varscan2
- CUL4B | c.1790T>C p.I597T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100340928; called by muse, varscan2
- DISP1 | c.4399T>G p.L1467V | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV99451739; called by muse, varscan2
- FKBP4 | c.1032+1G>A p.X344_splice | Splice Site (SNP) | VAF 31/65 reads (48%) | catalogued as rs1480490022, COSV99133902; called by muse, mutect2, varscan2
- KLHL8 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201977013, COSV99911509; called by muse, mutect2, varscan2
- NEBL | c.2519-2A>G p.X840_splice | Splice Site (SNP) | VAF 19/54 reads (35%) | catalogued as rs747461565, COSV101009298; called by muse, mutect2, varscan2
- PDZK1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV58260790; called by muse, mutect2, varscan2
- PRPF8 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs754605791, COSV100517741; called by muse, mutect2, varscan2
- SAP30BP | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV99502940; called by muse, mutect2, varscan2
- SYT4 | c.1039A>G p.K347E | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99674178; called by muse, mutect2, varscan2
- TTLL5 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as COSV100091135; called by muse, mutect2, varscan2
- ZNF485 | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as rs767351763, COSV100700261; called by muse, mutect2, varscan2
- ZNF560 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56871571; called by muse, mutect2, varscan2
- CTBP1 | c.158_160del p.F53del | In Frame Del (DEL) | VAF 33/91 reads (36%) | called by mutect2, pindel, varscan2
- VAV2 | c.1656_1657dup p.M553Tfs*17 (on ENST00000371850 / NM_001134398.2; = p.M543Tfs*17 on NM_003371.4) | Frame Shift Ins (INS) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- ZNF292 | c.95dup p.E33Gfs*55 | Frame Shift Ins (INS) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- BLVRB | c.621G>A p.*207= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99648023; called by muse, mutect2, varscan2
- CPSF1 | c.519C>T p.H173= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs782746758, COSV100574697; called by muse, mutect2, varscan2
- FRMD6 | c.1470G>A p.S490= (on ENST00000344768 / NM_001267046.2; = p.S482= on NM_152330.4) | Silent (SNP) | VAF 43/79 reads (54%) | catalogued as rs772963275, COSV61087271; called by muse, mutect2, varscan2
- HELB | c.864T>A p.T288= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as rs776864219, COSV99922097; called by muse, mutect2, varscan2
- LRCH1 | c.1023C>T p.D341= | Silent (SNP) | VAF 70/158 reads (44%) | catalogued as rs769156959, COSV100243924; called by muse, mutect2, varscan2
- NCOR1 | c.4611G>A p.G1537= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99251285; called by muse, mutect2, varscan2
- PMPCB | c.1287T>C p.Y429= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99971367; called by muse, mutect2
- TDRD1 | c.1185T>C p.C395= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as rs1200941445, COSV99314909; called by muse, mutect2, varscan2
